Gene-level copy-number profile of tumor specimen TCGA-16-1056-01B from TCGA case TCGA-16-1056, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 55.6 years (20,310 days).
Specimen TCGA-16-1056-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.4917b653-272d-446c-87f4-30188d2747ec.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-16-1056-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4e646906-edb5-4cc1-a29e-07c30b84197d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 9,026; copy number 2: 48,355; copy number 3: 2,266; copy number 4: 8; copy number 7: 1; copy number 8: 41; copy number 9: 96; copy number 10: 10; copy number 11: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-16-1056-01): tumor purity 0.78, ploidy 1.93, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 162 genes in 20 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:2,635,976–2,817,767, 5 genes, copy number 10 (within-gene range 2–10): TTC34, AC242022.2, AL592464.2, AL592464.3, AL592464.1.
- chr1:11,425,257–11,425,821, 1 gene, copy number 9: MTCYBP45.
- chr1:11,623,558–12,167,038, 34 genes, copy number 9: AL031731.1, FBXO2, FBXO44, FBXO6, MAD2L2, DRAXIN, AGTRAP, C1orf167, C1orf167-AS1, MTHFR, CLCN6, AL021155.2, AL021155.3, NPPA, AL021155.1, NPPB, SBF1P2, AL021155.4, RNU5E-1, RNU5E-4P, KIAA2013, PLOD1, AL096840.2, MFN2, AL096840.1, MIIP, Y_RNA, MIR6729, RN7SL649P, TNFRSF8, RNU6-777P, RPL23AP89, AL357835.1, MIR7846.
- chr1:15,326,680–15,343,876, 2 genes, copy number 9 (within-gene range 1–9): FHAD1-AS1, AL031283.2.
- chr1:15,807,169–16,073,651, 17 genes, copy number 8: UQCRHL, AL450998.1, FLJ37453, SPEN, AL034555.1, ZBTB17, AL355994.4, AL355994.1, AL355994.5, TBC1D3P6, SRARP, AL355994.3, HSPB7, CLCNKA, AL355994.2, CLCNKB, FAM131C.
- chr1:18,839,599–18,956,676, 5 genes, copy number 10: TAS1R2, ALDH4A1, MIR4695, MIR1290, IFFO2.
- chr1:19,424,384–19,424,671, 1 gene, copy number 9: RN7SL277P.
- chr1:19,510,593–19,510,733, 1 gene, copy number 9: RNU4-28P.
- chr1:20,525,989–20,526,751, 1 gene, copy number 7: RPS4XP4.
- chr1:21,822,244–21,956,871, 3 genes, copy number 8 (within-gene range 1–8): HSPG2, AL590556.1, AL590556.2.
- chr1:24,899,511–25,125,454, 8 genes, copy number 11: RUNX3, MIR6731, RUNX3-AS1, AL445471.1, MIR4425, LINC02793, AL050344.1, IFITM3P7.
- chr4:150,970,671–151,027,617, 2 genes, copy number 11: RNA5SP168, AK4P6.
- chr12:52,806,549–53,131,985, 16 genes, copy number 8 (within-gene range 1–8): KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3.
- chr12:53,708,517–53,898,976, 5 genes, copy number 8 (within-gene range 1–8): CALCOCO1, AC076968.2, CISTR, AC076968.1, RN7SKP289.
- chr12:57,128,483–57,846,729, 53 genes, copy number 9: LRP1, LRP1-AS, MIR1228, NXPH4, AC137834.2, SHMT2, NDUFA4L2, STAC3, AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM, AVIL, AC025165.5, RNU6-1083P, AC025165.4, CTDSP2, MIR26A2, AC083805.2.
- chr12:58,087,892–58,098,013, 2 genes, copy number 9: LINC02403, AC090643.1.
- chr12:58,872,149–58,920,504, 1 gene, copy number 9 (within-gene range 1–11): LRIG3.
- chr12:62,021,570–62,022,174, 1 gene, copy number 9: RPS3P6.
- chr12:63,623,788–63,795,718, 1 gene, copy number 11 (within-gene range 2–11): AC084357.2.
- chr12:63,682,523–63,809,562, 3 genes, copy number 11 (within-gene range 2–11): AC084357.3, AC084357.1, RXYLT1.

Autosomal genes at a single copy (total copy number 1): 6,646. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
